MMRF case MMRF_1718 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/bbceaec2-114b-4de5-a694-7d96078f9612

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 60 years; Vital status: Dead; Days to death: 682 days (1.9 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 60.4 years (22,058 days); ISS stage: I; Days to last known disease status: 682 days (1.9 years); Days to last follow up: 682 days (1.9 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 2 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 183 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 3 days; Days to treatment end: 183 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 205 days; Days to treatment end: 288 days.
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 205 days; Days to treatment end: 260 days.
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 261 days; Days to treatment end: 288 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 289 days; Days to treatment end: 410 days (1.1 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 418 days (1.1 years); Days to treatment end: 449 days (1.2 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 682.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 15 (ECOG 1): M Protein 2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 30.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.65 mg/dL; Immunoglobulin G 35.8 g/L; Immunoglobulin A 1.16 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 2.2 µg/mL; Lactate Dehydrogenase 1.78 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 125 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.4 mmol/L; Albumin 41 g/L; Total Protein 9 g/dL; Glucose 7.92 mmol/L; C-Reactive Protein 0.03 mg/dL.
- Day 92 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.45 mg/dL; Immunoglobulin G 5.73 g/L; Immunoglobulin A 0.29 g/L; Immunoglobulin M 0.14 g/L; Lactate Dehydrogenase 3.2 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 109 ×10⁹/L; Creatinine 96.4 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.38 mmol/L; Albumin 41 g/L; Total Protein 6 g/dL; Glucose 7.04 mmol/L.
- Day 183 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.74 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.91 mg/dL; Immunoglobulin G 4.89 g/L; Immunoglobulin A 0.32 g/L; Immunoglobulin M 0.1 g/L; Lactate Dehydrogenase 3.8 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 130 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Total Protein 5.8 g/dL; Glucose 11.2 mmol/L.
- Day 288 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.23 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.93 mg/dL; Immunoglobulin G 4.16 g/L; Immunoglobulin A 0.54 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 113 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.28 mmol/L; Albumin 37 g/L; Total Protein 5.9 g/dL; Glucose 9.13 mmol/L.
- Day 372 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.98 mg/dL; Immunoglobulin G 9.11 g/L; Immunoglobulin A 1.17 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 3.93 µkat/L; Hemoglobin 5.46 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 290 ×10⁹/L; Creatinine 157 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.18 mmol/L; Albumin 37 g/L; Total Protein 6.6 g/dL; Glucose 6.55 mmol/L.
- Day 449 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.77 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.79 mg/dL; Immunoglobulin G 5.39 g/L; Immunoglobulin A 0.51 g/L; Immunoglobulin M 0.1 g/L; Lactate Dehydrogenase 2.62 µkat/L; Hemoglobin 5.58 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.28 mmol/L; Albumin 30 g/L; Total Protein 5.6 g/dL; Glucose 9.41 mmol/L.
- Day 555 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.27 mg/dL; Immunoglobulin G 8.03 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 3 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 152 ×10⁹/L; Creatinine 94.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.5 mmol/L; Albumin 47 g/L; Total Protein 7.3 g/dL; Glucose 6.93 mmol/L.
- Day 624 (ECOG 2): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 81.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.98 mg/dL; Immunoglobulin G 9.13 g/L; Immunoglobulin A 0.7 g/L; Immunoglobulin M 1.13 g/L; Lactate Dehydrogenase 3.32 µkat/L; Hemoglobin 5.83 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 229 ×10⁹/L; Creatinine 123 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.45 mmol/L; Albumin 31 g/L; Total Protein 6.5 g/dL; Glucose 9.74 mmol/L.

Other clinical attributes
- Day 15: Weight: 92 kg; Height: 177 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Prostate Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1718_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 15 days.
- Sample MMRF_1718_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 15 days.
